Somatic mutation profile of tumor specimen MMRF_1908_1_BM_CD138pos (aliquot MMRF_1908_1_BM_CD138pos_T1_KHS5U_L08108) from MMRF case MMRF_1908, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.1 years (24,887 days).
Specimen MMRF_1908_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c22cf0c8-90cd-4088-abaf-83266ce63457.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1908_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1908_1_PB_WBC_C2_KHS5U_L08109; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2227c785-9ae0-43dc-a754-9bd38037eb4e

The open-access MAF lists 35 somatic variants for this specimen: 14 protein-altering or splice-affecting, 6 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, 3'UTR 12, Silent 6, 5'Flank 1, Frame Shift Ins 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 35/116 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- LZTR1 | c.416A>G p.D139G | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53146351; called by muse, mutect2, varscan2
- MYT1L | c.1297C>A p.L433M | Missense Mutation (SNP) | VAF 30/218 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67720462; called by muse, mutect2, varscan2
- CLHC1 | c.479A>T p.D160V | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by muse, mutect2
- DNHD1 | c.4663G>T p.A1555S | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FRAT2 | c.477G>T p.Q159H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- HNRNPR | c.949T>G p.W317G | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.107); called by muse, varscan2
- KLHDC7A | c.1045C>A p.P349T | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PCSK5 | c.3310T>A p.F1104I | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); called by muse, mutect2
- RYR3 | c.4290A>T p.E1430D | Missense Mutation (SNP) | VAF 7/181 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.054); called by muse, mutect2
- TRAF3 | c.530dup p.C177Wfs*57 | Frame Shift Ins (INS) | VAF 9/22 reads (41%) | called by mutect2, pindel, varscan2
- TYRP1 | c.1061G>C p.S354T | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- VPS13B | c.10051G>T p.V3351L | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- WEE2 | c.200A>G p.D67G | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHD5 | c.1653G>T p.P551= | Silent (SNP) | VAF 23/70 reads (33%) | called by muse, mutect2, varscan2
- HIPK1 | c.1080T>A p.A360= | Silent (SNP) | VAF 43/282 reads (15%) | catalogued as rs148540287; called by muse, mutect2, varscan2
- PXDN | c.73C>T p.L25= | Silent (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2
- ROBO2 | c.630A>C p.G210= | Silent (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- XDH | c.486C>T p.T162= | Silent (SNP) | VAF 18/150 reads (12%) | called by muse, varscan2
- ZNF695 | c.1101G>C p.L367= | Silent (SNP) | VAF 24/131 reads (18%) | called by muse, mutect2, varscan2
- ABCC9 | c.*2908T>C | 3'UTR (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- ADGRA1 | c.*728G>C | 3'UTR (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2, varscan2
- ATP5PB | c.*555G>T | 3'UTR (SNP) | VAF 18/24 reads (75%) | called by muse, varscan2
- C20orf194 | c.*1203T>C | 3'UTR (SNP) | VAF 51/100 reads (51%) | called by muse, mutect2
- DACH1 | chr13:71867201 G>T | 5'Flank (SNP) | VAF 12/15 reads (80%) | called by muse, mutect2, varscan2
- DNM1P47 | n.656G>A | RNA (SNP) | VAF 17/132 reads (13%) | catalogued as rs550818955; called by muse, mutect2, varscan2
- MIPOL1 | c.*5215T>G | 3'UTR (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2, varscan2
- PREX2 | c.*4550T>A | 3'UTR (SNP) | VAF 20/60 reads (33%) | called by muse, mutect2, varscan2
- RNF144A | c.*1053C>T | 3'UTR (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- SLC7A6 | c.*1059A>G | 3'UTR (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- SNTB2 | c.*3472T>C | 3'UTR (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- TMC5 | c.2439+70G>A | Intron (SNP) | VAF 36/77 reads (47%) | called by muse, mutect2, varscan2
- TROAP | c.*56C>T | 3'UTR (SNP) | VAF 11/275 reads (4%) | catalogued as COSV57745329; called by muse, mutect2
- VPS51 | c.*190C>T | 3'UTR (SNP) | VAF 16/75 reads (21%) | called by muse, mutect2, varscan2
- YIPF5 | c.*1093del | 3'UTR (DEL) | VAF 32/80 reads (40%) | called by mutect2, varscan2
